Surgical pathology report (de-identified scan), TCGA case TCGA-55-8619, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8619-01A (Primary Tumor).

[page 1 of 8]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - M.) LUNG, RIGHT, LYMPH NODES, N4R, N4R#2, N4R#3, N10R, N7, N10L, N4L, N2R, N7, N7#2, LYMPH NODE BIOPSIES AND RESECTIONS, WEDGE RESECTIONS (X2), AND COMPLETION PNEUMONECTOMY:

- Adenocarcinoma with mucinous features, well differentiated.
- Two foci in right lower lobe, 1.5 cm in greatest dimension each.
- One focus in right upper lobe, 2.0 cm in greatest dimension.
- Visceral pleural invasion present, tumor does not extend to pleural surface.
- Surgical margins negative.
- Twenty-two lymph nodes, no tumor seen (0/22).
- See comment.

PATHOLOGIC TUMOR STAGING SYNOPSIS (Right lower lobe):

Type and grade: Adenocarcinoma, well differentiated.

Primary tumor: pT3(2 tumor foci).

Regional lymph nodes: pN0.

Distant metastasis: N/A.

Pathologic stage: IIB.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

PATHOLOGIC TUMOR STAGING SYNOPSIS (Right upper lobe):

Type and grade: Adenocarcinoma, well differentiated.

Primary tumor: pT2a.

Regional lymph nodes: pN0.

Distant metastasis: N/A.

Pathologic stage: IB.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

COMMENT: Sections show three histologically similar foci of adenocarcinoma with areas of definitive invasion and areas of a mucinous bronchioloalveolar pattern. The tumor cells are diffusely, strongly positive for CK7 and show patchy positivity for

[page 2 of 8]
FINAL SURGICAL PATHOLOGY REPORT

CDX2 and villin and are negative for CK20, TTF-1, and Napsin-A. There are three foci of adenocarcinoma identified (two in the right lower lobe and one in the right upper lobe). The differential diagnosis includes adenocarcinoma of lung primary versus metastatic adenocarcinoma of gastrointestinal primary (upper GI, pancreato-biliary and colon). Lung primary adenocarcinomas are typically positive for CK7, TTF-1 and Napsin-A and negative for CDX2, villin and CK20, however, lung primary adenocarcinomas with mucinous differentiation can show patchy positivity for CDX2. Three tumor foci are seen in the lung, which can be seen in the setting of metastatic disease and a multifocal lung primary. The diffusely, strongly positive CK7, patchy CDX2 positivity, negative CK20, and the presence of a bronchioloalveolar growth pattern favor a lung primary origin, therefore, the patient is staged accordingly, however, metastatic gastrointestinal adenocarcinoma cannot be completely excluded. Because the patient has no lymphovascular invasion, negative lymph nodes and associated bronchioloalveolar growth pattern, the right upper lobe and right lower lobe are staged separately.

[page 3 of 8]
Procedure:

Specimen type:

Specimen laterality:

Specimen integrity:

Tumor Features:

Tumor site:

Tumor size:

Tumor focality:

Histologic type:

Histologic grade:

Lymphovascular invasion:

Perineural invasion:

Visceral pleural invasion:

Tumor extension into extra-pulmonary structures:

Treatment effect:

Lymph Nodes:

Margin Evaluation:

Distance to closest margin:

Bronchial margin:

Vascular margin:

Parenchymal margin:

Parietal pleural margin:

Chest wall margin:

Other margins:

Pathologic tumor staging descriptors:

Primary tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

Margin status (R):

Pathologic stage:

Additional pathologic findings:

Comment:

Multiple lymph node biopsies and resections, right upper lobe and right lower lobe lobectomies, and right lung resection.

Right upper lobe, right lower lobe, right lung resection, multiple lymph node biopsies and resections.

Right.

Intact.

Right upper lobe, right lower lobe.

Multifocal, Right upper lobe: 2.0; right lower lobe two foci: 1.5 and 1.5 cm.

Multifocal.

Adenocarcinoma with mucinous features.

Well differentiated (G1).

Not identified.

Not identified.

PL1, tumor extends into visceral pleura but does not extend to pleural surface (seen in both the right upper lobe and right lower lobe).

Not identified.

N/A.

Twenty-two lymph nodes, no tumor seen.

Parietal pleura at 0.1 cm.

Greater than 2 cm.

Greater than 2 cm.

Greater than 2 cm.

0.1 cm.

N/A.

N/A.

Right lower lobe/Right upper lobe.

Right lower lobe pT3; Right upper lobe pT2a.

pN0.

N/A.

R0, negative.

Right lower lobe IIB; Right upper lobe IB.

Emphysematous changes.

N/A.

[page 4 of 8]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. N4R
- B. N4R#2
- C. N10R
- D. N7
- E. N10L
- F. N4L
- G. N2R
- H. Lung;right lower wedge lobe resection
- I. Lung;right upper lobe wedge resection
- J. Lung;right lung
- K. N4R #3
- L. N7#2
- M. N7

Clinical History/Operative Dx:

Right lung cancer.

Intraoperative Diagnosis:

- A. (FSA) Lymph node, N4R excision:
- Benign lymph node.
- B. (FSB) Lymph node, N4R #2, excision:
- Benign lymph node.
- C. (FSC) Lymph node, N10R excision:
- Benign lymph node.
- D. (FSD) Lymph node, N7, excision:
- Benign lymph node.
- E. (FSE) Lymph node, N10L, excision:
- Benign lymph node.
- F. (FSF) Lymph node, N4L, excision:
- Benign lymph node.

[page 5 of 8]
FINAL SURGICAL PATHOLOGY REPORT

G. (FSG) Lymph node, N2R, excision:
- Benign lymph node.

H. (FSH1-2) Lung, right lower lobe, resection:
- Adenocarcinoma (two nodules).

I. (FSI) Lung, right lung upper lobe, resection:
- Adenocarcinoma.

J. (FSJ) Lung, right, resection:
- Bronchial margins free of tumor.

Gross Description:

A. Part A is labeled [REDACTED]. Initially received in the fresh state for frozen section analysis is a single speckled, darkened gray lymph node candidate, 7 x 5 x 5 mm. The specimen is bisected and submitted for frozen section analysis. The residual frozen tissue is submitted for permanent sections in A1. [REDACTED]

B. Part B is labeled [REDACTED]. Initially received in the fresh state for frozen section analysis is a yellow-tan portion of fatty soft tissue measuring 1.4 x 1.3 x 0.5 cm. Examination reveals a 6 x 5 x 4 mm lymph node candidate. The lymph node candidate is entirely submitted for frozen section analysis with the residual frozen tissue submitted in B1 for permanent sections. The remaining fragments submitted for routine histology in B2. [REDACTED]

C. Part C is labeled as [REDACTED]. Initially received in the fresh state for frozen section analysis is a rubbery, light pink to gray lymph node candidate, 1.2 x 1.0 x 0.6 cm. The specimen is serially sectioned and entirely submitted for frozen section analysis, with the residual frozen tissue submitted in C1 for permanent sections. [REDACTED]

D. Part D is labeled [REDACTED]. Initially received in the fresh state for frozen section analysis is a multilobular light pink to darkened gray portion of soft tissue, 1.3 x 1.0 x 0.5 cm. The specimen is serially sectioned demonstrating possible multiple lymph node candidates up to 0.6 cm. The tissue is entirely submitted for frozen section analysis, with the residual frozen tissue submitted in D1 for permanent sections. [REDACTED]

E. Part E is labeled [REDACTED]. Initially received for frozen section is a light tan to speckled darkened gray lymph node candidate, 13 x 9 x 7 mm. The lymph node is trisected and entirely submitted for frozen section analysis with the residual frozen tissue submitted in E1. [REDACTED]

F. Part F is labeled a [REDACTED]. Initially received in the fresh state for frozen section analysis is a single fatty yellow to darkened gray lymph node candidate, 5 x 4 x 3 mm. The lymph node is entirely submitted for frozen section analysis with the residual frozen tissue submitted in F1 for permanent sections. [REDACTED]

[page 6 of 8]
FINAL SURGICAL PATHOLOGY REPORT

G. Part G is labeled [REDACTED] Initially received in the fresh state for frozen section analysis is a lobular fragment of yellow-tan fatty soft tissue with speckled darkened gray changes, 8 x 6 x 5 mm. The lymph node is bisected and entirely submitted for frozen section analysis with the residual frozen tissue submitted in G1 for permanent sections. [REDACTED]

H. Initially received in the fresh state for frozen section analysis is a wedge of lung, 13.5 x 4 x 3.5 cm and 25 grams. The pleura is glistening, light pink to deep purple with two dimpled areas with underlying palpable density. The surface of both sites are now marked blue and black, respectively to larger and smaller nodules. The surgical margin of resection is closed by numerous surgical staples, involving approximately 0.6 cm of the lung.

Sectioning through the aforementioned sites of palpable density, reveals two irregular, however, grossly well-demarcated, light gray tumor nodules, 1.5 cm each. Both lesions abut the aforementioned, dimpled pleura, and the smaller lesion grossly approaches within 0.8 cm of the surgical margin. The larger lesion grossly approaching within 1.2 cm of the surgical margin. Representative section of each lesion is submitted for frozen section analysis (chuck/block) with the residual frozen tissue submitted in H1 for permanent sections. Representative portion of the larger tumor is submitted for Oncogenotyping studies with additional representation of paraneoplastic and normal lung tissue also submitted.

The remaining cut sections of the wedge of lung demonstrates spongy, light pink to slightly consolidated parenchyma without additional nodularity. Representative sections are submitted for microscopic evaluation.

Cassette summary: H1) frozen section, both smaller and larger nodules represented, H2-H3) larger nodule, overlying pleura represented, four pieces, H4) margin previously involved with surgical staples adjacent to the tumor, trimmed and submitted en face, H5-H6) smaller nodule including overlying pleura represented, four pieces, H7) surgical margin formally involved with surgical margins adjacent to small lesion, trimmed and submitted en face [REDACTED]

I. Part I is labeled right lung upper lobe wedge resection. Initially received in the fresh state for frozen section analysis is a wedge of lung, 6.0 x 2.5 x 1.5 cm and 7 grams. The overlying pleura is glistening, light tan to purple-red with a slightly dimpled area with underlying palpable mass. Initial sectioning reveals an irregular, however, grossly well-demarcated tumor nodule measuring up to 2.0 x 1.0 x 0.9 cm. Representative section is submitted for frozen section analysis with the residual frozen tissue submitted in I1 for permanent sections. Following initial sectioning, the pleura overlying the tumor is marked blue. The surgical margin adjacent to the tumor is involved with numerous surgical staples (0.6 cm), is now trimmed, and the resolving margin is marked black. The remaining cut sections of the wedge demonstrates a spongy, light pink and tan parenchyma without additional discrete nodularity. Representative sections are submitted for microscopic evaluation.

Cassette summary: I1) frozen section of tumor, I2-I3) additional representation of tumor, five pieces, I4) uninvolved lung tissue represented. [REDACTED]

J. Part J designated right lung, frozen section bronchial margin. Initially received in a fresh state for frozen section analysis is a right pneumonectomy, 18.7 x 16.3 x 4.2 cm, and 370 grams. The overlying pleura is [REDACTED]

[page 7 of 8]
FINAL SURGICAL PATHOLOGY REPORT

glistening with a variegated light pink to purple and speckled dark gray appearance. The upper and lower lobes demonstrating two lines of surgical staples, 9.8 cm and 12.3 cm, respectively, corresponding to the former wedge resections or frozen section analysis. A palpable mass is not appreciated. The central main bronchial margin is 2.3 cm in diameter and extends out to 2.0 cm; the bronchial margin associated with the upper lobe is 2.0 cm in diameter and extending out to 0.9 cm. The upper and lower main lobar tracts are partially occluded with hemorrhagic mucin plug, however, no gross tumor involvement is appreciated.

The bronchial margins is now trimmed and submitted for frozen section analysis, with the residual frozen tissue submitted in J1 for permanent sections. Sectioning through the remainder of the lung demonstrates partially consolidated, deep red, hemorrhagic lung parenchyma, with peripheral spongy, light pink and tan tissue. The lobar and gross segmental tracts are free of tumor involvement. No additional discrete nodularity appreciated. Representative sections are submitted for microscopic evaluation.

Cassette summary: J1) bronchial margins, frozen section, J2) vascular surgical margins trimmed and submitted, J3) five hilar lymph node candidates, peribronchial, J4-J5) upper lobe represented, three pieces, J6-J7) lower lobe represented, three pieces.

K. Part K is labeled . Received in formalin are multiple lobular and tattered fragments of fatty soft tissue including lymph node candidacy, measuring in aggregate 5.5 x 2.8 x 1.1 cm. Examination reveals six lymph node candidates ranging from 5 x 3 mm to 17 x 13 mm each. The lymph node tissue demonstrates softened light tan to speckled dark gray appearance. The lymph node tissue is entirely submitted for microscopic evaluation.

Cassette summary: K1) largest lymph node, sectioned and submitted, K2) two lymph node candidates, K3) three lymph node candidates.

L. Part L is labeled . Received in formalin are two tattered fragments of light pink to darkened gray soft tissue including lymph node candidacy, measuring in aggregate 1.3 x 1.3 x 0.7 cm. Examination reveals a tattered lymph node candidate measuring up to 7 mm. The specimen is entirely submitted for microscopic evaluation in L1.

M. Part M is labeled . Received in formalin is a single tattered, darkened gray anthracotic lymph node candidate, 11 x 7 x 5 mm. The specimen fragments easily upon manipulation and is entirely submitted for microscopic evaluation in M1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show one lymph node with no metastatic carcinoma identified.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show one lymph node with no metastatic carcinoma identified.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show one lymph node with no metastatic carcinoma identified.

[page 8 of 8]
FINAL SURGICAL PATHOLOGY REPORT

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show fragments of lymph node with no metastatic carcinoma identified.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show one lymph node with no metastatic carcinoma identified.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show one lymph node with no metastatic carcinoma identified.

G. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show one lymph node with no metastatic carcinoma identified.

H. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for CK7, CK20, CK5/6, p63, CDX2, ER, Pax-8, Napsin-A, TTF-1, Villin and S-100. The tumor cells stain as follows:

Tumor cells positive: CK7, villin (patchy), CDX2 (patchy)

Tumor cells negative: CK20, S-100, Napsin-A, TTF-1, CK5/6, PAX-8, p63, [REDACTED]

I. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

J. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Six lymph nodes are seen with no metastatic carcinoma identified.

K. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Seven lymph nodes are seen with no metastatic carcinoma identified.

L. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. One lymph node is seen with no metastatic carcinoma identified.

M. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. One lymph node is seen with no metastatic carcinoma identified.

[REDACTED]

Source: NCI Genomic Data Commons file 533c0f37-9630-4595-968e-700c8d7785cf (TCGA-55-8619.DCBC1E01-C61A-4D30-B741-965C99418ECF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).